Somatic mutation profile of tumor specimen TARGET-20-PAMYAS-09A (aliquot TARGET-20-PAMYAS-09A-01D) from TARGET case TARGET-20-PAMYAS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.9 years (3,972 days).
Specimen TARGET-20-PAMYAS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b371125c-80f3-4242-be0f-3b123048c780.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAMYAS-14A (Bone Marrow Normal), aliquot TARGET-20-PAMYAS-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04bd9936-fd84-4314-8eda-086652176843

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 55/242 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTSA | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs199916179, COSV51944460; called by muse, mutect2, varscan2
- NEXMIF | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV50082317; called by muse, mutect2, varscan2
- NLGN2 | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV57211718; called by muse, mutect2, varscan2
- OR5D13 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV62335019; called by muse, mutect2, varscan2
- PCSK4 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV99960539; called by muse, mutect2
- THBS1 | c.2648C>A p.A883D | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.946); catalogued as rs1025026532, COSV52955185; called by muse, mutect2, varscan2
- CSF3R | c.2456_2457insATAG p.F819Lfs*2 | Nonsense Mutation (INS) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- C8A | c.1395C>T p.H465= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs201408238; called by muse, mutect2, varscan2
